Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7794, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7794-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN FIVE (5) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SIX (6) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $3 + 4 = 7$.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- C. THE CARCINOMA INVOLVES 10% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3.
- L. BENIGN PROSTATIC HYPERPLASIA IN THE BACKGROUND.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	31.04gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	10
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

PATIENT HISTORY:

The patient is a [REDACTED]-year-old [REDACTED] male with a history of PSA value of 5.2. The patient also has a history of biopsy on [REDACTED], this biopsy reveals: poorly-differentiated prostatic adenocarcinoma, Gleason score $3+4 = 7$ in the right apex and Gleason score $4+3 = 7$ in the right mid of the prostate. The patient also has a history of hypertension, gastroesophageal reflux disease, hypercholesterolemia and cardiac stent NIDD.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

Source: NCI Genomic Data Commons file 2d1b535c-fbb6-417d-82f6-f0cb9e2011d3 (TCGA-EJ-7794.73164D62-BC3A-4DD3-8201-86C5F35EF168.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).